MMRF case MMRF_2006 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/250eadda-919e-4267-a958-c9385068267c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.2 years (22,351 days); ISS stage: II; Days to last known disease status: 855 days (2.3 years); Days to last follow up: 855 days (2.3 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 855.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 2): M Protein 4.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 66.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 72.3 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 12 g/dL; Glucose 5.72 mmol/L.
- Day 92 (ECOG 1): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 7.7 mmol/L.
- Day 175 (ECOG 2): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 9.75 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 8.31 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.29 mg/dL; Immunoglobulin G 8.29 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.8 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7.8 g/dL; Glucose 4.95 mmol/L.
- Day 365: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 7.91 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 6.71 mmol/L.
- Day 449: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 7.71 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 6.88 mmol/L.
- Day 533: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 7.8 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 7.9 g/dL; Glucose 6.49 mmol/L.
- Day 617 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.94 mg/dL; Immunoglobulin G 9.26 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 6.27 mmol/L.
- Day 729 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 9.16 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 6.22 mmol/L.
- Day 820: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 7.94 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.81 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 8.03 mmol/L.

Other clinical attributes
- Day -10: Weight: 114 kg; Height: 188 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2006_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2006_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
